Gene-level copy-number profile of tumor specimen C3L-03385-04 from CPTAC case C3L-03385, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.3 years (26,404 days).
Specimen C3L-03385-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file be4a2a18-0f37-434e-8d04-46015b56d166.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03385-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/f8715a62-8906-4a49-87ab-0fae4730515e

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 107; copy number 1: 3; copy number 2: 1,534; copy number 3: 1,320; copy number 4: 18,832; copy number 5: 24,288; copy number 6: 8,572; copy number 7: 818; copy number 8: 2,828; copy number 9: 22; copy number 10: 12; copy number 11: 10; copy number 12: 40; copy number 15: 6.

Homozygous deletions (total copy number 0; autosomes only): 107 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:3,218,297–3,691,814, 5 genes: RFX3, AL354941.1, RFX3-AS1, AL354977.2, AL354977.1.
- chr9:14,081,843–14,472,407, 4 genes: NFIB, AL441963.1, AL136366.1, AL137017.1.
- chr9:19,789,179–23,956,444, 83 genes (broad region; genes not listed).
- chr10:25,393,557–25,393,844, 1 gene (within-gene range 0–4): RN7SKP220.
- chr10:79,661,394–79,826,594, 1 gene (within-gene range 0–4): NUTM2B-AS1.
- chr10:79,703,227–79,714,681, 1 gene (within-gene range 0–4): NUTM2B.
- chr11:80,321,620–80,957,634, 5 genes: AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1.
- chr14:106,440,950–106,443,583, 2 genes (within-gene range 0–4): IGHVII-40-1, IGHV3-41.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–4): IGHV3-43.
- chr22:28,883,572–29,061,844, 4 genes (within-gene range 0–3): ZNRF3, ZNRF3-IT1, ZNRF3-AS1, C22orf31.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 56 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–91,105, 10 genes, copy number 11: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.3.
- chr7:38,269,491–38,300,322, 6 genes, copy number 15 (within-gene range 8–15): TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.
- chr7:142,636,924–142,802,748, 35 genes, copy number 12: TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBJ2-2P, TRBJ2-3, TRBJ2-4, TRBJ2-5, TRBJ2-6, TRBJ2-7, TRBC2.
- chr21:12,999,676–13,120,807, 5 genes, copy number 12: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
